Somatic mutation profile of tumor specimen TCGA-HV-A5A5-01A (aliquot TCGA-HV-A5A5-01A-11D-A26I-08) from TCGA case TCGA-HV-A5A5, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 61.1 years (22,329 days).
Specimen TCGA-HV-A5A5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aea6a437-39a9-4875-8994-000d7498a115.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HV-A5A5-10A (Blood Derived Normal), aliquot TCGA-HV-A5A5-10A-01D-A26I-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f126a946-8a6f-40c5-839d-e5f62619ab15

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.614A>T p.Y205F | Missense Mutation (SNP) | VAF 22/231 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2
- ADAMTS20 | c.986C>T p.T329I | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101240321; called by muse, mutect2
- ANK2 | c.7702T>G p.C2568G | Missense Mutation (SNP) | VAF 59/663 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV100004127; called by muse, mutect2
- CD226 | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs1318587433, COSV99711498; called by muse, mutect2
- CDH10 | c.1292T>C p.I431T | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV100053050; called by muse, mutect2
- DOCK8 | c.4438C>G p.H1480D | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV101210071, COSV101210135; called by muse, mutect2
- GPR174 | c.350T>A p.F117Y | Missense Mutation (SNP) | VAF 62/852 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV99338373; called by muse, mutect2
- KLHL32 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100987491; called by muse, mutect2
- LRRTM4 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV69139056; called by muse, mutect2
- MT1B | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 43/558 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs200369659, COSV57618884; called by muse, mutect2
- PHKA2 | c.1036G>C p.V346L | Missense Mutation (SNP) | VAF 37/467 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV101177436; called by muse, mutect2
- PSG4 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 119/1803 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as rs754987366, COSV54939356; called by muse, mutect2
- ANKRD50 | c.1833T>C p.G611= | Silent (SNP) | VAF 21/547 reads (4%) | catalogued as COSV101539045; called by muse, mutect2
- CCDC88B | c.2718G>C p.L906= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as COSV100105887; called by muse, mutect2, varscan2
- CDKN2AIP | c.1608C>T p.L536= | Silent (SNP) | VAF 34/489 reads (7%) | catalogued as rs1560949487, COSV100187724; called by muse, mutect2
- MMP13 | c.1233T>A p.I411= | Silent (SNP) | VAF 16/228 reads (7%) | catalogued as COSV99506842; called by muse, mutect2
- PCK2 | c.1062C>T p.A354= | Silent (SNP) | VAF 106/817 reads (13%) | catalogued as COSV99394678; called by muse, mutect2, varscan2
- POF1B | c.1347G>A p.L449= | Silent (SNP) | VAF 30/470 reads (6%) | catalogued as COSV99427377; called by muse, mutect2
